HCMI case HCM-BROD-0755-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b0f583f9-177a-4578-ad47-908b8023ff99

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive.

Diagnoses (2)
1. Lentigo maligna melanoma (the primary disease): ICD-O-3 morphology code: 8742/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,812 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T1b; AJCC pathologic N: N2b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 633 days (1.7 years); Days to treatment end: 992 days (2.7 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Metastasis of the skin (histology not recorded by GDC). ICD-10 code: C77.9; Site of resection or biopsy: Lymph node, NOS; Age at diagnosis: 64.0 years (23,393 days); Days to diagnosis: 581 days (1.6 years); Satellite nodule present: Absent.
   Pathology details: Breslow thickness category: <=1 mm; Lymph nodes positive: 3; Lymph nodes tested: 13; Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 1,031 days (2.8 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 603.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 86 kg; Height: 162 cm; BMI: 32.8.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0755-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0755-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
